Somatic mutation profile of tumor specimen TCGA-EJ-7794-01A (aliquot TCGA-EJ-7794-01A-11D-2114-08) from TCGA case TCGA-EJ-7794, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.0 years (24,478 days).
Specimen TCGA-EJ-7794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdcd0e7e-d5f6-4a94-9287-f96a7bf1c8be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7794-10A (Blood Derived Normal), aliquot TCGA-EJ-7794-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efc5477-0073-4059-a100-e3d14a2bc531

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN2A | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs121917753, CM040797, COSV51836018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.679G>T p.D227Y (on ENST00000392977 / NM_001286615.2; = p.D192Y on NM_178826.4) | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV54589646; called by muse, mutect2, varscan2
- ATP9A | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 8/215 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125633, COSV58764528; called by muse, mutect2
- GATA5 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV99435554; called by muse, mutect2
- LAMA2 | c.6201_6203del p.K2067del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs758495000; called by pindel, varscan2
- MAN1A1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63781646; called by muse, mutect2, varscan2
- PTPRA | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV53779708; called by muse, mutect2, varscan2
- STK32C | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV53838949; called by muse, mutect2
- SUPT6H | c.3781A>G p.M1261V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.747); catalogued as COSV58925719; called by muse, mutect2, varscan2
- USP15 | c.1176A>C p.L392F (on ENST00000280377 / NM_001351159.2; = p.L363F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54789696; called by muse, mutect2, varscan2
- MAN2A1 | c.1812del p.L605Ffs*4 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- FIBCD1 | c.1275C>T p.R425= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs747715759, COSV53392801; called by muse, mutect2, varscan2
- SMG5 | c.2595C>T p.C865= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- OSCAR | c.*380del | 3'UTR (DEL) | VAF 4/10 reads (40%) | catalogued as COSV99034438; called by mutect2, varscan2
